Gene-level copy-number profile of tumor specimen TCGA-FR-A7U8-06A from TCGA case TCGA-FR-A7U8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.2 years (18,698 days).
Specimen TCGA-FR-A7U8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.587cd5e2-22e1-461b-a051-f31e4a05f515.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A7U8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/55c168fc-8145-40d7-a3e3-794ff59aeefc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 12,591; copy number 2: 40,835; copy number 3: 5,611; copy number 4: 604; copy number 5: 159.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A7U8-06A-21D-A34T-01): tumor purity 0.89, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:152,448,275–152,779,730, 9 genes (within-gene range 0–1): AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1, TIGD4.
- chr4:152,796,063–152,796,831, 1 gene: NSA2P6.
- chr4:181,522,666–181,523,001, 1 gene: AC093840.1.
- chr10:87,994,618–87,994,695, 1 gene: AC063965.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 159 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:7,620,422–7,620,878, 1 gene, copy number 5: AL390026.1.
- chr13:90,060,247–100,675,093, 158 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
